Somatic mutation profile of tumor specimen C3L-01607-02 (aliquot CPT0092170009) from CPTAC case C3L-01607, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 83.4 years (30,462 days).
Specimen C3L-01607-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 599a331f-f0dc-4cf9-87ce-6151552189ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01607-31 (Blood Derived Normal), aliquot CPT0093750002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b07e2568-5255-4160-87a4-78031860af4d

The open-access MAF lists 127 somatic variants for this specimen: 87 protein-altering or splice-affecting, 21 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 21, Intron 8, Frame Shift Del 8, 3'UTR 5, Nonsense Mutation 4, Splice Site 4, 5'Flank 3, RNA 2, Splice Region 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB3 | c.880G>A p.V294M | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as rs747355273; called by muse, varscan2
- BBX | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 36/244 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772688060, COSV57881501; called by muse, mutect2, varscan2
- CELSR2 | c.8533C>T p.P2845S | Missense Mutation (SNP) | VAF 38/281 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs1218934903; called by muse, mutect2, varscan2
- CYP2A13 | c.773C>A p.T258K | Missense Mutation (SNP) | VAF 58/318 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs138089886, COSV57836209; called by muse, mutect2, varscan2
- DHRS9 | c.384G>C p.E128D | Missense Mutation (SNP) | VAF 53/242 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.026); catalogued as rs1439921018, COSV59139683; called by muse, mutect2, varscan2
- EIF5A | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 32/276 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.308); catalogued as COSV100222692; called by muse, mutect2, varscan2
- ESX1 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV65424475; called by muse, mutect2, varscan2
- EXOC5 | c.887G>T p.R296M | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV61770803; called by muse, mutect2, varscan2
- FAM71B | c.1328G>C p.S443T | Missense Mutation (SNP) | VAF 56/295 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs767349540, COSV57231403; called by muse, mutect2, varscan2
- FOXD4 | c.22C>G p.R8G | Missense Mutation (SNP) | VAF 79/589 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.042); catalogued as COSV58700483; called by muse, mutect2, varscan2
- FYB2 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV58587469; called by muse, mutect2
- GTF2H1 | c.1418G>A p.R473Q | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as rs551071012, COSV56377387; called by muse, mutect2, varscan2
- KMT2D | c.5140C>A p.P1714T | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as COSV56494634; called by muse, mutect2, varscan2
- MAPT | c.1135C>T p.H379Y (on ENST00000262410 / NM_001377265.1; = p.H304Y on NM_016835.4) | Missense Mutation (SNP) | VAF 66/371 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1213524576, COSV99291158, COSV99291236; called by muse, mutect2, varscan2
- MAST2 | c.3820C>T p.R1274* | Nonsense Mutation (SNP) | VAF 6/137 reads (4%) | catalogued as COSV100788838, COSV63616207, COSV63618152; called by muse, mutect2
- NUP188 | c.4663C>G p.L1555V | Missense Mutation (SNP) | VAF 27/461 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV65330459; called by muse, mutect2
- PRAMEF17 | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 30/738 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs1157534354, COSV101068750; called by muse, mutect2
- RASSF10 | c.670C>G p.R224G | Missense Mutation (SNP) | VAF 15/187 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as rs994986909; called by muse, mutect2
- SERPINH1 | c.565A>T p.T189S | Missense Mutation (SNP) | VAF 34/189 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.418); catalogued as rs138784081; called by muse, mutect2, varscan2
- SLC3A2 | c.1711G>T p.D571Y | Missense Mutation (SNP) | VAF 69/304 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as rs931124662; called by muse, mutect2, varscan2
- SUZ12 | c.1278A>T p.L426F | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); catalogued as rs773744548; called by muse, mutect2, varscan2
- THSD7A | c.2466G>C p.K822N | Missense Mutation (SNP) | VAF 40/209 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV70265705; called by muse, mutect2, varscan2
- TMEM25 | c.974_976del p.N325del | In Frame Del (DEL) | VAF 38/285 reads (13%) | catalogued as rs1555061837; called by pindel, varscan2
- AHDC1 | c.3638C>A p.S1213Y | Missense Mutation (SNP) | VAF 47/251 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ATP2C1 | c.2129G>A p.S710N | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- BPIFB6 | c.267A>C p.Q89H | Missense Mutation (SNP) | VAF 40/274 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- C1GALT1 | c.158A>C p.D53A | Missense Mutation (SNP) | VAF 40/253 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC32 | c.349C>G p.Q117E | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- CD4 | c.1304T>A p.I435N | Missense Mutation (SNP) | VAF 25/266 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CERS1 | c.822_823insT p.V275Cfs*3 | Frame Shift Ins (INS) | VAF 43/224 reads (19%) | called by mutect2, pindel, varscan2
- CFAP43 | c.2495A>C p.E832A | Missense Mutation (SNP) | VAF 43/178 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CHST9 | c.1080T>A p.C360* | Nonsense Mutation (SNP) | VAF 36/255 reads (14%) | called by muse, mutect2, varscan2
- CRP | c.439G>C p.A147P | Missense Mutation (SNP) | VAF 68/384 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CTDSPL2 | c.973del p.Y325Mfs*2 | Frame Shift Del (DEL) | VAF 15/101 reads (15%) | called by mutect2, pindel, varscan2
- CTSA | c.616A>G p.N206D | Missense Mutation (SNP) | VAF 77/433 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DEFB118 | c.352_364del p.N118Afs*26 | Frame Shift Del (DEL) | VAF 16/111 reads (14%) | called by mutect2, pindel
- DLG5 | c.895C>G p.L299V | Missense Mutation (SNP) | VAF 52/283 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- DPYSL3 | c.923G>T p.S308I | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2
- EDC4 | c.1606C>G p.P536A | Missense Mutation (SNP) | VAF 22/356 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2
- EVPL | c.1624G>T p.E542* | Nonsense Mutation (SNP) | VAF 51/309 reads (17%) | called by muse, mutect2, varscan2
- FAM186B | c.466T>A p.C156S | Missense Mutation (SNP) | VAF 91/490 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- FAM227A | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 37/215 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GON4L | c.5996T>C p.V1999A | Missense Mutation (SNP) | VAF 59/418 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HIGD1A | c.134del p.L45Yfs*4 | Frame Shift Del (DEL) | VAF 32/191 reads (17%) | called by mutect2, pindel, varscan2
- HTATSF1 | c.2201_2208del p.E734Afs*12 | Frame Shift Del (DEL) | VAF 18/80 reads (23%) | called by mutect2, pindel
- HYKK | c.783del p.Y262Mfs*12 | Frame Shift Del (DEL) | VAF 42/318 reads (13%) | called by mutect2, pindel, varscan2
- IGDCC4 | c.3180+2T>G p.X1060_splice | Splice Site (SNP) | VAF 37/664 reads (6%) | called by muse, mutect2
- IL9 | c.252A>T p.R84S | Missense Mutation (SNP) | VAF 20/391 reads (5%) | SIFT tolerated (0.6); PolyPhen benign (0.007); called by muse, mutect2
- IRF8 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 62/336 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- KCNG1 | c.1280A>G p.Y427C | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KDM5C | c.3682A>T p.T1228S | Missense Mutation (SNP) | VAF 65/172 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- KDM5C | c.3121-15_3133del p.X1041_splice | Splice Site (DEL) | VAF 20/173 reads (12%) | called by mutect2, pindel
- KNG1 | c.544G>A p.V182I | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- KRCC1 | c.440G>C p.S147T | Missense Mutation (SNP) | VAF 42/211 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- LIN28A | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 23/188 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MEFV | c.385G>C p.G129R | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, mutect2
- MGA | c.8713G>C p.E2905Q (on ENST00000219905 / NM_001164273.1; = p.E2696Q on NM_001080541.2) | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- MINK1 | c.2011A>G p.R671G | Missense Mutation (SNP) | VAF 64/328 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- MINK1 | c.2012G>T p.R671M | Missense Mutation (SNP) | VAF 63/326 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- MROH9 | c.1440T>A p.D480E | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NACA | c.235-1G>T p.X79_splice | Splice Site (SNP) | VAF 13/85 reads (15%) | called by muse, mutect2, varscan2
- PARD3 | c.1147A>G p.S383G | Missense Mutation (SNP) | VAF 59/362 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- PARD6B | c.518T>C p.I173T | Missense Mutation (SNP) | VAF 44/235 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PBRM1 | c.3604A>C p.T1202P (on ENST00000296302 / NM_001366071.2; = p.T1177P on NM_018313.5) | Missense Mutation (SNP) | VAF 33/179 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHA6 | c.122A>G p.H41R | Missense Mutation (SNP) | VAF 53/409 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PCLO | c.9839T>A p.M3280K | Missense Mutation (SNP) | VAF 38/249 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- PSD | c.943A>G p.I315V | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- RPL10A | c.67C>G p.R23G | Missense Mutation (SNP) | VAF 68/369 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEL1L3 | c.2586-16_2586-5del | Splice Region (DEL) | VAF 17/136 reads (13%) | called by mutect2, pindel, varscan2
- SH2B1 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- SKP1 | c.370G>C p.A124P | Missense Mutation (SNP) | VAF 68/516 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC25A13 | c.1514C>A p.A505D | Missense Mutation (SNP) | VAF 85/533 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SLC25A13 | c.1513G>A p.A505T | Missense Mutation (SNP) | VAF 85/537 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SMYD4 | c.502G>T p.D168Y | Missense Mutation (SNP) | VAF 60/317 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- SPTAN1 | c.2967G>T p.K989N | Missense Mutation (SNP) | VAF 72/399 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SPTAN1 | c.2968A>T p.K990* | Nonsense Mutation (SNP) | VAF 69/393 reads (18%) | called by muse, mutect2, varscan2
- STRA6 | c.1721T>A p.V574D | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); called by muse, mutect2
- SV2B | c.1724T>C p.I575T | Missense Mutation (SNP) | VAF 86/512 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- TANC1 | c.263C>G p.P88R | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.759); called by muse, mutect2
- TERT | c.1951-1G>A p.X651_splice | Splice Site (SNP) | VAF 23/459 reads (5%) | called by muse, mutect2
- TEX14 | c.2507del p.P836Lfs*73 (on ENST00000240361 / NM_001201457.2; = p.P830Lfs*73 on NM_031272.5) | Frame Shift Del (DEL) | VAF 26/167 reads (16%) | called by mutect2, pindel, varscan2
- TOX4 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- VHL | c.387_390del p.V130Tfs*28 | Frame Shift Del (DEL) | VAF 50/277 reads (18%) | called by mutect2, pindel, varscan2
- ZCCHC14 | c.1382T>A p.L461Q (on ENST00000268616; = p.L598Q on NM_015144.3) | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZDHHC2 | c.450T>G p.I150M | Missense Mutation (SNP) | VAF 38/187 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- ZFPM1 | c.387del p.R130Gfs*9 | Frame Shift Del (DEL) | VAF 50/295 reads (17%) | called by mutect2, pindel, varscan2
- ZNF687 | c.3065T>C p.V1022A | Missense Mutation (SNP) | VAF 47/265 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ACACA | c.5250C>T p.R1750= | Silent (SNP) | VAF 58/382 reads (15%) | called by muse, mutect2, varscan2
- CD4 | c.1305C>T p.I435= | Silent (SNP) | VAF 25/267 reads (9%) | catalogued as COSV50589947; called by muse, mutect2
- CPT1A | c.189T>A p.L63= | Silent (SNP) | VAF 68/472 reads (14%) | called by muse, mutect2, varscan2
- DCUN1D4 | c.513T>C p.D171= | Silent (SNP) | VAF 16/94 reads (17%) | called by muse, varscan2
- GPLD1 | c.1062C>T p.F354= | Silent (SNP) | VAF 28/184 reads (15%) | called by muse, mutect2, varscan2
- HEXA | c.882C>T p.L294= | Silent (SNP) | VAF 18/348 reads (5%) | called by muse, mutect2
- KIF19 | c.1995C>T p.P665= | Silent (SNP) | VAF 32/182 reads (18%) | catalogued as rs1016773272, COSV63430705; called by muse, mutect2, varscan2
- KMT2B | c.4224C>A p.A1408= | Silent (SNP) | VAF 17/132 reads (13%) | called by muse, mutect2, varscan2
- MAPT | c.1791T>C p.T597= (on ENST00000262410 / NM_001377265.1; = p.T205= on NM_005910.5) | Silent (SNP) | VAF 40/311 reads (13%) | called by muse, mutect2, varscan2
- MB | c.345T>G p.V115= | Silent (SNP) | VAF 25/116 reads (22%) | called by muse, mutect2, varscan2
- NALCN | c.114T>G p.V38= | Silent (SNP) | VAF 14/84 reads (17%) | called by muse, mutect2, varscan2
- PEG10 | c.768G>A p.A256= (on ENST00000482108 / NM_001040152.2; = p.A290= on NM_015068.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/250 reads (4%) | called by muse, mutect2
- RHOXF2 | c.396C>T p.N132= | Silent (SNP) | VAF 79/503 reads (16%) | catalogued as rs782065383; called by muse, mutect2, varscan2
- SH3RF3 | c.2259C>T p.D753= | Silent (SNP) | VAF 22/153 reads (14%) | catalogued as rs1322906700; called by muse, mutect2, varscan2
- SLC16A2 | c.996C>T p.A332= | Silent (SNP) | VAF 101/281 reads (36%) | catalogued as rs1232946549; called by muse, mutect2, varscan2
- SLFNL1 | c.597T>C p.S199= | Silent (SNP) | VAF 27/193 reads (14%) | called by muse, mutect2, varscan2
- SP1 | c.57A>G p.K19= (on ENST00000327443 / NM_138473.3; = p.K12= on NM_003109.1) | Silent (SNP) | VAF 22/131 reads (17%) | called by muse, mutect2, varscan2
- TBX6 | c.1215A>G p.V405= | Silent (SNP) | VAF 48/214 reads (22%) | called by muse, mutect2, varscan2
- TOGARAM2 | c.1386G>A p.T462= | Silent (SNP) | VAF 52/224 reads (23%) | catalogued as rs527747733, COSV65423208; called by muse, mutect2, varscan2
- UQCR10 | c.168C>T p.I56= | Silent (SNP) | VAF 49/301 reads (16%) | called by muse, mutect2, varscan2
- ZMYM2 | c.1794A>G p.T598= | Silent (SNP) | VAF 24/197 reads (12%) | called by muse, mutect2, varscan2
- AC107023.1 | chr12:40444228 C>T | 5'Flank (SNP) | VAF 20/314 reads (6%) | catalogued as rs1461313887; called by muse, mutect2
- BIRC8 | n.1459T>A | RNA (SNP) | VAF 22/149 reads (15%) | called by muse, mutect2, varscan2
- CD276 | c.*36G>A | 3'UTR (SNP) | VAF 10/75 reads (13%) | called by muse, mutect2, varscan2
- ECM2 | chr9:92536054 del TGC | 5'UTR (DEL) | VAF 31/181 reads (17%) | called by mutect2, pindel, varscan2
- EIF4E | c.*42C>A | 3'UTR (SNP) | VAF 20/144 reads (14%) | called by muse, mutect2
- GP2 | chr16:20327559 T>A | 5'Flank (SNP) | VAF 55/303 reads (18%) | called by muse, mutect2, varscan2
- HNRNPH1 | c.*21T>C | Intron (SNP) | VAF 8/47 reads (17%) | catalogued as COSV61486881; called by muse, mutect2
- IFT52 | c.*19C>G | 3'UTR (SNP) | VAF 28/178 reads (16%) | called by muse, mutect2, varscan2
- MARK2 | c.55-6234A>G | Intron (SNP) | VAF 33/258 reads (13%) | called by muse, mutect2, varscan2
- MEIS2 | c.1147+408G>A | Intron (SNP) | VAF 43/253 reads (17%) | called by muse, mutect2, varscan2
- NCKAP1 | c.3181-34A>C | Intron (SNP) | VAF 26/147 reads (18%) | called by muse, mutect2, varscan2
- PDE3B | c.1029+100_1029+102del | Intron (DEL) | VAF 9/44 reads (20%) | called by mutect2, pindel, varscan2
- REXO1L1P | n.766C>A | RNA (SNP) | VAF 74/734 reads (10%) | called by muse, mutect2, varscan2
- SEPTIN1 | c.*221C>A | 3'UTR (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- SKOR1 | chr15:67824742 C>T | 5'Flank (SNP) | VAF 11/145 reads (8%) | called by muse, mutect2
- SORBS1 | c.2129-988T>C | Intron (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- TMA16 | c.*528C>G | 3'UTR (SNP) | VAF 8/43 reads (19%) | catalogued as rs1019892970; called by muse, mutect2, varscan2
- TPM1 | c.772+68C>G | Intron (SNP) | VAF 49/280 reads (18%) | called by muse, mutect2, varscan2
- VASP | c.873+16T>A | Intron (SNP) | VAF 28/187 reads (15%) | called by muse, mutect2, varscan2
